Gene-level copy-number profile of specimen HCM-BROD-0761-C71-85B from HCMI case HCM-BROD-0761-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.4 years (22,788 days).
Specimen HCM-BROD-0761-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b381900d-3c60-4dfd-8a1e-1649938e0e27.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0761-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/ca896f0d-7f7e-4fb1-8eb0-7bbb377a313d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 7,950; copy number 2: 42,302; copy number 3: 8,650; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,586,136–15,669,044, 6 genes (within-gene range 0–2): AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1.
- chr6:163,413,065–163,413,960, 1 gene: CAHM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,898,805–61,911,022, 1 gene, copy number 9: FAM242E.

Autosomal genes at a single copy (total copy number 1): 5,250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
